Somatic mutation profile of tumor specimen BA3095D (aliquot aq-BA3095D) from BEATAML1.0 case 2626, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 27.1 years (9,892 days).
Specimen BA3095D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f122f606-9170-4c5d-8c30-0ef58e5530b3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3233D (Solid Tissue Normal), aliquot aq-BA3233D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5d84fff0-ea03-4606-ae7b-ec20b6fa6025

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- E2F8 | c.1910G>A p.G637E | Missense Mutation (SNP) | VAF 77/162 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MEF2A | c.728A>G p.N243S (on ENST00000557942 / NM_001319206.2; = p.N245S on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 56/147 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- PAPSS2 | c.140T>A p.L47Q | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- UBTF | c.1294_1302delinsGTC p.L432_E434delinsV | In Frame Del (DEL) | VAF 6/24 reads (25%) | called by pindel, varscan2*
